Somatic mutation profile of tumor specimen TCGA-KM-8639-01A (aliquot TCGA-KM-8639-01A-11D-2397-10) from TCGA case TCGA-KM-8639, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 67.5 years (24,640 days).
Specimen TCGA-KM-8639-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38e7cced-9454-40d9-a152-736e6c49c3c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KM-8639-10A (Blood Derived Normal), aliquot TCGA-KM-8639-10A-01D-2397-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69a35665-8c85-4846-8fbf-9a37a9a84971

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Frame Shift Del 3, Silent 2, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCE1 | c.1580A>G p.Y527C | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99668409; called by muse, mutect2
- CDK13 | c.3671C>G p.P1224R | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV51704270; called by muse, mutect2, varscan2
- SEC23IP | c.19A>C p.N7H | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV100957091; called by muse, mutect2, varscan2
- ANKRD17 | c.1738_1741del p.V580Nfs*4 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | called by pindel, varscan2
- BIRC3 | c.1572T>G p.H524Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GPR158 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | called by muse, varscan2
- HCFC1 | c.3265A>G p.N1089D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYBPHL | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- MYO18B | c.6066G>C p.Q2022H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- OSER1 | c.828C>G p.Y276* | Nonsense Mutation (SNP) | VAF 44/132 reads (33%) | called by muse, varscan2
- PACS1 | c.2489A>G p.H830R | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, varscan2
- PARD3B | c.2181dup p.S728Ifs*34 (on ENST00000406610 / NM_001302769.2; = p.S728Ifs*6 on NM_057177.7) | Frame Shift Ins (INS) | VAF 42/202 reads (21%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.10750G>A p.A3584T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- TANGO6 | c.2492C>G p.S831C | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TMED1 | c.490_496del p.R164Sfs*82 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | called by mutect2, pindel, varscan2
- TRIM22 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TSC1 | c.2153_2162del p.R718Pfs*3 | Frame Shift Del (DEL) | VAF 80/121 reads (66%) | called by mutect2, pindel, varscan2
- APOL5 | c.816G>A p.T272= | Silent (SNP) | VAF 20/228 reads (9%) | catalogued as rs370593513; called by muse, mutect2
- CNOT4 | c.1266A>G p.E422= (on ENST00000315544 / NM_001190848.1; = p.E419= on NM_013316.4) | Silent (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2, varscan2
- MRPS34 | c.365-18C>T | Intron (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
